Gene-level copy-number profile of tumor specimen TCGA-64-1676-01A from TCGA case TCGA-64-1676, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 58.7 years (21,428 days).
Specimen TCGA-64-1676-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.1a04f32c-fe4e-4603-8a2f-c27fc86a9fc3.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-64-1676-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/9c13d621-1707-42db-b48d-9d5b6d01f33f

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 494; copy number 2: 21,408; copy number 3: 9,488; copy number 4: 21,545; copy number 5: 2,590; copy number 6: 1,746; copy number 7: 2,158; copy number 8: 35; copy number 9: 94; copy number 10: 53; copy number 13: 51; copy number 14: 87; copy number 15: 13; copy number 16: 55; copy number 20: 2.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-64-1676-01A-01D-0944-01): tumor purity 0.51, ploidy 1.72, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 6,884 genes in 17 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–248,919,946, 2,604 genes, copy number 5–7 (broad region; genes not listed).
- chr2:37,325,340–38,067,142, 13 genes, copy number 15 (within-gene range 3–15): AC007391.1, RNU6-939P, AC007391.2, QPCT, RNU6-1116P, AC007391.3, AC006369.1, CDC42EP3, AC006369.2, AC010878.1, LINC00211, RMDN2, RMDN2-AS1.
- chr2:43,675,151–43,681,622, 2 genes, copy number 20: C1GALT1C1L, AC011242.1.
- chr2:46,816,697–60,439,828, 166 genes, copy number 9–16 (broad region; genes not listed).
- chr2:70,252,918–81,666,728, 211 genes, copy number 5–7 (broad region; genes not listed).
- chr2:113,157,325–113,209,396, 1 gene, copy number 5 (within-gene range 4–5): PSD4.
- chr2:113,211,421–124,989,325, 138 genes, copy number 5–14 (broad region; genes not listed).
- chr5:35,048,756–37,753,435, 46 genes, copy number 6: PRLR, AC010368.1, U3, SPEF2, RNU7-130P, AC137810.1, IL7R, AC112204.3, AC112204.1, CAPSL, AC112204.2, UGT3A1, UGT3A2, AC016612.1, LMBRD2, MIR580, SKP2, RNU6-1305P, NADK2, NADK2-AS1, RANBP3L, AC114277.1, RNA5SP181, AC010631.1, SLC1A3, AC008957.2, AC008957.1, AC008957.3, AC026741.1, NIPBL-DT, NIPBL, KRT18P31, RPS4XP6, CPLANE1, RBISP2, OFD1P17, RN7SL37P, AC025449.2, AC025449.1, NUP155, RNU7-75P, AC117532.1, WDR70, KCTD9P5, RNU6-1190P, RNU6-484P.
- chr8:92,460,539–145,066,685, 856 genes, copy number 6–7 (within-gene range 4–7) (broad region; genes not listed).
- chr9:4,709,556–14,594,200, 126 genes, copy number 5–14 (within-gene range 3–14) (broad region; genes not listed).
- chr9:108,626,833–116,402,321, 138 genes, copy number 5–9 (broad region; genes not listed).
- chr9:134,992,958–135,354,284, 6 genes, copy number 6: AL353611.2, OLFM1, AL390778.1, AL390778.2, C9orf62, AL353615.1.
- chr14:28,264,390–43,314,803, 226 genes, copy number 5–9 (broad region; genes not listed).
- chr16:46,469,341–90,222,851, 1,141 genes, copy number 6 (broad region; genes not listed).
- chr17:62,122,320–83,095,122, 698 genes, copy number 5 (broad region; genes not listed).
- chr20:45,293,445–64,313,132, 495 genes, copy number 5 (broad region; genes not listed).
- chr21:23,982,645–25,381,756, 17 genes, copy number 6 (within-gene range 3–6): AP000477.3, AP000477.1, AP000470.1, LINC01689, LINC01684, LINC01692, AP000402.1, AP000146.1, AP001342.1, AP000235.1, AP000233.2, RN7SKP236, AP000233.1, AP001341.1, RNA5SP489, RPL13AP7, AP001340.1.

Autosomal genes at a single copy (total copy number 1): 7. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
